Somatic mutation profile of tumor specimen TCGA-85-8048-01A (aliquot TCGA-85-8048-01A-11D-2244-08) from TCGA case TCGA-85-8048, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.7 years (22,907 days).
Specimen TCGA-85-8048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 726e5913-d496-4757-81b4-c2368b221945.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8048-10A (Blood Derived Normal), aliquot TCGA-85-8048-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/989318e6-8c54-404f-85da-43de99f7436c

The open-access MAF lists 105 somatic variants for this specimen: 81 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 22, Nonsense Mutation 3, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV99288137; called by muse, mutect2, varscan2
- ADCY10 | c.3560T>A p.V1187E | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV100896667; called by muse, mutect2, varscan2
- ASTN1 | c.2054+2T>G p.X685_splice | Splice Site (SNP) | VAF 16/144 reads (11%) | catalogued as COSV56063445, COSV99920863; called by muse, mutect2, varscan2
- ATN1 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.993); catalogued as rs1197306327, COSV100755717, COSV100755813; called by muse, mutect2, varscan2
- BMP10 | c.431A>C p.E144A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99770328; called by muse, mutect2, varscan2
- CAMTA1 | c.2668C>A p.L890I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100347355; called by muse, mutect2
- CCM2 | c.87T>G p.D29E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV99347599; called by muse, mutect2
- CDK8 | c.511A>C p.I171L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV101037033; called by muse, mutect2
- CDKN2A | c.293A>C p.H98P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.647); catalogued as COSV58683927, COSV58696031; called by muse, mutect2, varscan2
- COL5A3 | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV99318400; called by muse, mutect2
- CPXM2 | c.2009T>C p.I670T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99581382; called by muse, mutect2, varscan2
- CR2 | c.299A>T p.Y100F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV100889551; called by muse, mutect2, varscan2
- CYP39A1 | c.662G>C p.W221S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150060177; called by muse, varscan2
- CYRIA | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100838271; called by muse, mutect2, varscan2
- DCAF12L2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1338664181, COSV63580237, COSV63583223; called by muse, mutect2, varscan2
- DUOX2 | c.2903C>T p.T968I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101199641; called by muse, mutect2, varscan2
- FAM166A | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs1257180644, COSV100457761, COSV61118205; called by muse, mutect2
- GALNT12 | c.879G>C p.R293S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as COSV100899084; called by muse, mutect2, varscan2
- GCSAML | c.255T>A p.N85K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV100825906; called by muse, mutect2
- GPR158 | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100892973, COSV66267725; called by mutect2, varscan2
- GRM1 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); catalogued as COSV99264838; called by muse, mutect2
- IGHMBP2 | c.1778A>G p.E593G | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54821857; called by muse, mutect2
- IGLV1-44 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as rs547379435; called by muse, mutect2, varscan2
- ISX | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570030565, COSV100434031, COSV100434149; called by muse, mutect2, varscan2
- ITLN2 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100600704; called by muse, mutect2, varscan2
- KCNV1 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52086938, COSV99818957; called by muse, mutect2, varscan2
- LAMA3 | c.860A>C p.Y287S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100555849; called by muse, mutect2, varscan2
- LAMP3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99660400; called by muse, mutect2, varscan2
- LDLR | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99369690; called by muse, mutect2
- LLGL2 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389208; called by muse, mutect2
- LRP2 | c.13886G>C p.R4629T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99787124; called by muse, mutect2, varscan2
- LSM1 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100258304; called by muse, mutect2, varscan2
- MAP3K12 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99913063; called by muse, mutect2
- MTSS1 | c.2111G>A p.S704N | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as rs770268664, COSV99412716; called by muse, mutect2
- MYBPH | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as rs1378137861, COSV99703839; called by muse, mutect2, varscan2
- NFATC1 | c.377T>C p.L126S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.776); catalogued as COSV99501004; called by muse, varscan2
- NOX4 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV99629966; called by muse, mutect2, varscan2
- NSUN4 | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100197350; called by muse, mutect2, varscan2
- OR2G2 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV100189648; called by muse, mutect2
- OR2H1 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV101009799; called by muse, mutect2, varscan2
- OR2M5 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1459341565, COSV100822765; called by muse, mutect2
- OR6C74 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59605712; called by muse, mutect2
- PACS2 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV100330640, COSV100330862; called by muse, mutect2, varscan2
- PCDHA9 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV100969222; called by muse, mutect2, varscan2
- PCDHGB2 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99533599; called by muse, mutect2
- PEG3 | c.2543A>T p.N848I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55649943, COSV99687894; called by muse, mutect2, varscan2
- PKD1L2 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100449691; called by mutect2, varscan2
- PKHD1 | c.5021T>C p.V1674A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100581859; called by muse, mutect2, varscan2
- PNLIPRP2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs376811919; called by muse, mutect2, varscan2
- PPP1R3A | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99492274; called by muse, mutect2, varscan2
- PPP3CC | c.125T>C p.L42S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99251881; called by muse, mutect2, varscan2
- PRODH2 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99995211; called by muse, mutect2
- PROZ | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs775089037, COSV61440395; called by muse, mutect2, varscan2
- PRRT2 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54884792, COSV99569391; called by muse, mutect2, varscan2
- PTPRH | c.2186C>A p.A729D | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99670825; called by muse, mutect2, varscan2
- PTPRM | c.3392G>A p.R1131Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100155864, COSV100158822; called by muse, mutect2
- RASGRF2 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); catalogued as rs767665990, COSV99428751; called by mutect2, varscan2
- RCAN1 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100571611; called by muse, mutect2, varscan2
- RNMT | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100054513; called by muse, mutect2, varscan2
- RRH | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774028833, COSV100496011; called by muse, mutect2, varscan2
- RTCB | c.761T>A p.V254E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53278408, COSV99322001; called by muse, mutect2, varscan2
- SCARF1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV53958362; called by muse, mutect2, varscan2
- SLC17A6 | c.339+1G>T p.X113_splice | Splice Site (SNP) | VAF 5/89 reads (6%) | catalogued as COSV99581037; called by muse, mutect2
- SMARCC2 | c.2924C>T p.T975I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV99519278; called by muse, mutect2
- SPAG1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308608; called by muse, mutect2, varscan2
- SV2C | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100455846; called by muse, mutect2
- TEX45 | c.989A>T p.Q330L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV100861797; called by muse, mutect2, varscan2
- TMPRSS11E | c.1064G>C p.R355T | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100542270; called by muse, mutect2
- TPST2 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100113996; called by muse, mutect2
- TTN | c.3419A>G p.K1140R (on ENST00000591111; = p.K1094R on NM_003319.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen benign (0); catalogued as COSV100600572; called by muse, mutect2, varscan2
- TULP3 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV101237491; called by muse, mutect2, varscan2
- UBR5 | c.2658G>T p.E886D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV99639945; called by muse, mutect2, varscan2
- USP6 | c.1518T>A p.S506R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100003424; called by muse, mutect2, varscan2
- XPNPEP2 | c.1666C>A p.P556T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941439; called by muse, mutect2, varscan2
- ZBTB17 | c.563C>A p.A188E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.067); catalogued as COSV100998981, COSV100999017; called by muse, mutect2, varscan2
- ZNF223 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs758648231, COSV101462608; called by muse, mutect2
- ZNF33B | c.166C>G p.H56D | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100847636, COSV100847708; called by muse, mutect2
- ZSCAN22 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV100308301; called by muse, mutect2, varscan2
- IGHG4 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- IGKV1D-43 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ADORA1 | c.219A>T p.P73= | Silent (SNP) | VAF 49/303 reads (16%) | catalogued as COSV100526209; called by muse, mutect2, varscan2
- ATP6V0E2 | c.178C>T p.L60= (on ENST00000425642; = p.L109= on NM_145230.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV101374574; called by muse, mutect2, varscan2
- C1orf54 | c.279G>A p.V93= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs892689820, COSV100961744; called by muse, mutect2, varscan2
- COA1 | c.204C>T p.L68= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99786472; called by muse, mutect2, varscan2
- EBF1 | c.1231C>T p.L411= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100565436; called by muse, mutect2, varscan2
- FBXO41 | c.1644A>C p.P548= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV99721021; called by muse, mutect2
- H4C5 | c.213G>A p.V71= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs779424083, COSV63486292; called by muse, mutect2, varscan2
- IL1A | c.150A>G p.Q50= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs760758291, COSV99641292; called by muse, mutect2, varscan2
- LRRIQ4 | c.1035G>A p.L345= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100540140; called by muse, mutect2, varscan2
- MYH7B | c.999C>T p.I333= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99482470; called by muse, mutect2
- MYO10 | c.4836A>G p.K1612= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99944908; called by muse, mutect2, varscan2
- NTRK3 | c.882T>C p.N294= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100446048; called by muse, varscan2
- OR6C74 | c.231C>A p.P77= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100667708; called by muse, mutect2
- PAX7 | c.531G>A p.E177= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100946651; called by muse, mutect2
- PCDHGA10 | c.1692C>T p.P564= | Silent (SNP) | VAF 28/338 reads (8%) | catalogued as COSV99533601; called by muse, mutect2
- POU3F2 | c.762G>T p.A254= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as rs1252802628, COSV100099060; called by muse, mutect2
- RNF113B | c.384C>A p.L128= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99940295; called by muse, mutect2, varscan2
- SHKBP1 | c.1938G>A p.G646= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99182945, COSV99199659; called by muse, mutect2, varscan2
- SLC5A11 | c.762G>T p.R254= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV100762713; called by muse, mutect2
- STK10 | c.768G>T p.T256= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99451131; called by muse, mutect2
- TNKS1BP1 | c.2691T>C p.Y897= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV100835874; called by muse, mutect2
- ZIC2 | c.1584T>C p.N528= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100891768; called by muse, mutect2, varscan2
- DST | c.4297-1077G>A | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99752780; called by muse, mutect2
- SNORD115-31 | n.61C>T | RNA (SNP) | VAF 8/188 reads (4%) | catalogued as rs1382196303; called by muse, mutect2
